Somatic mutation profile of tumor specimen TCGA-D1-A17L-01A (aliquot TCGA-D1-A17L-01A-11D-A12J-09) from TCGA case TCGA-D1-A17L, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 81.9 years (29,899 days).
Specimen TCGA-D1-A17L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12fc0b91-a78b-4263-9cf6-f9fa4a5e35a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17L-10A (Blood Derived Normal), aliquot TCGA-D1-A17L-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76d157a1-b578-4c53-b980-9847562afdf8

The open-access MAF lists 76 somatic variants for this specimen: 63 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 57, Silent 13, Nonsense Mutation 2, Translation Start Site 1, In Frame Ins 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 123/329 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- METTL14 | c.893G>C p.R298P | Missense Mutation (SNP) | VAF 133/393 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310162, COSV66310354; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 195/260 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 318/433 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs750791458, COSV56642065; called by muse, mutect2, varscan2
- ANO9 | c.2343C>A p.D781E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV60382429; called by muse, mutect2
- ATRIP | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 62/200 reads (31%) | catalogued as COSV57175890, COSV57177589; called by muse, mutect2, varscan2
- BEND2 | c.2122G>C p.V708L | Missense Mutation (SNP) | VAF 113/348 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV66215081; called by muse, mutect2, varscan2
- CAMK2A | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1160671001, COSV62244965, COSV62245410; called by muse, mutect2, varscan2
- CEP192 | c.3748C>G p.L1250V | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV58059957; called by muse, mutect2, varscan2
- CEP68 | c.193A>T p.T65S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV53123483, COSV53128292; called by muse, mutect2, varscan2
- CEP97 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.179); catalogued as rs1364690600, COSV59122687; called by muse, mutect2, varscan2
- CFAP251 | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs754845886, COSV56607989; called by muse, mutect2, varscan2
- CPXM2 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 170/560 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs754686014, COSV53856331; called by muse, mutect2, varscan2
- DENND4C | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs144291586; called by muse, mutect2, varscan2
- EFNB1 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52660987; called by muse, mutect2, varscan2
- EHHADH | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 81/98 reads (83%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV51627788; called by muse, mutect2, varscan2
- EPX | c.472C>G p.P158A | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56594937; called by muse, mutect2, varscan2
- FAM135B | c.3207G>T p.Q1069H | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52705848, COSV52716524; called by muse, mutect2, varscan2
- FIGLA | c.305G>A p.S102N | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV60088658; called by muse, mutect2, varscan2
- HS1BP3 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs760156212, COSV58311926; called by muse, mutect2, varscan2
- IMPDH1 | c.692A>T p.D231V (on ENST00000470772 / NM_001142573.2; = p.D317V on NM_000883.4) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV58314970; called by muse, mutect2, varscan2
- KMT2B | c.1546A>C p.K516Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV52889422, COSV99386062; called by muse, varscan2
- LRG1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.719); catalogued as rs1431003592, COSV56702391; called by muse, mutect2, varscan2
- MEGF10 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765084824, COSV57245112, COSV57247382; called by muse, mutect2, varscan2
- MSX1 | c.653T>A p.I218K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66946967; called by muse, mutect2
- NMUR1 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as rs766623480, COSV59403469, COSV59404620; called by muse, mutect2
- NQO2 | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57642347; called by muse, mutect2, varscan2
- OR2B11 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs1216004925, COSV59509260, COSV59511813; called by muse, mutect2, varscan2
- OR5A1 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 97/281 reads (35%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.992); catalogued as COSV57375775; called by muse, mutect2, varscan2
- PCDHA10 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as rs17844338, COSV56478495; called by muse, mutect2, varscan2
- PCDHB10 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV53375461; called by muse, mutect2, varscan2
- PCDHB9 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53379089; called by muse, mutect2
- PLCD4 | c.706A>C p.K236Q | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.076); catalogued as COSV68842108; called by muse, mutect2, varscan2
- POU4F2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1438913081, COSV55582902; called by muse, mutect2, varscan2
- PPP1R10 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV64738482; called by muse, mutect2, varscan2
- PREX1 | c.2056T>C p.S686P | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV64247921; called by muse, mutect2, varscan2
- PRMT1 | c.771C>G p.I257M | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as COSV67159161, COSV67160561; called by muse, mutect2, varscan2
- PTPRJ | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs374139660; called by muse, mutect2
- RC3H2 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 59/173 reads (34%) | catalogued as COSV59010416; called by muse, mutect2, varscan2
- RPL3L | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs564278385, COSV51905266; called by muse, mutect2, varscan2
- RXFP3 | c.324C>A p.S108R | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs866700301, COSV57504106; called by muse, mutect2, varscan2
- RYR3 | c.8740A>C p.I2914L (on ENST00000389232; = p.I2915L on NM_001036.6) | Missense Mutation (SNP) | VAF 150/388 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.069); catalogued as COSV66778323; called by muse, mutect2, varscan2
- S100A5 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV62876523, COSV62876611; called by muse, mutect2, varscan2
- SFXN3 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 373/950 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV56519066; called by muse, mutect2, varscan2
- SMAP1 | c.898C>T p.L300F (on ENST00000370455 / NM_001044305.3; = p.L273F on NM_021940.5) | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57635381; called by muse, mutect2
- SMOC1 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 160/451 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62759516; called by muse, mutect2, varscan2
- SVEP1 | c.8185C>T p.R2729C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as rs202205164, COSV52835598, COSV99929868; called by muse, mutect2, varscan2
- SYMPK | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV55609615; called by muse, mutect2
- SYNE1 | c.22166T>G p.I7389S (on ENST00000367255 / NM_182961.4; = p.I7318S on NM_033071.3) | Missense Mutation (SNP) | VAF 147/401 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54909927; called by muse, mutect2, varscan2
- TMEM255A | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.031); catalogued as COSV59028024; called by muse, mutect2, varscan2
- TMEM259 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs144593243, COSV52258655; called by muse, varscan2
- TNFAIP1 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV56875813; called by muse, mutect2, varscan2
- TTC16 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs554814365, COSV60159870; called by muse, mutect2, varscan2
- VPS36 | c.578A>C p.E193A | Missense Mutation (SNP) | VAF 260/683 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as COSV65198631; called by muse, mutect2, varscan2
- XPNPEP2 | c.1930C>T p.H644Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV64368437; called by muse, mutect2
- ZNF462 | c.1599G>A p.M533I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV52930610; called by muse, mutect2, varscan2
- ZNF462 | c.4286G>T p.C1429F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.146); catalogued as rs1217559389, COSV52930621; called by muse, mutect2, varscan2
- ARHGAP18 | c.1034_1044+9del p.X345_splice | Splice Site (DEL) | VAF 85/372 reads (23%) | called by mutect2, pindel, varscan2
- MMP28 | c.838C>A p.Q280K | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2
- MYO19 | c.2774A>T p.H925L (on ENST00000614623 / NM_001163735.1; = p.H725L on NM_025109.5) | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- RBM39 | c.1189dup p.I397Nfs*12 | Frame Shift Ins (INS) | VAF 99/332 reads (30%) | called by mutect2, pindel, varscan2
- TRIP12 | c.4386_4391dup p.T1463_F1464insLT | In Frame Ins (INS) | VAF 170/643 reads (26%) | called by mutect2, varscan2
- ASXL3 | c.6576C>T p.N2192= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as rs373489061; called by muse, mutect2, varscan2
- C18orf54 | c.438C>T p.H146= | Silent (SNP) | VAF 62/197 reads (31%) | catalogued as COSV55617366; called by muse, mutect2, varscan2
- CCDC80 | c.2271C>A p.G757= | Silent (SNP) | VAF 140/473 reads (30%) | catalogued as COSV52815011; called by muse, mutect2, varscan2
- EIF3D | c.753C>T p.I251= | Silent (SNP) | VAF 74/185 reads (40%) | catalogued as COSV53402696; called by muse, mutect2, varscan2
- FGD1 | c.570C>A p.A190= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV64308096; called by muse, mutect2
- HCFC1 | c.4398C>T p.I1466= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs781900488, COSV60069505; called by muse, mutect2, varscan2
- NLRX1 | c.768G>A p.T256= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs199539903, COSV52701512, COSV99424307; called by muse, mutect2, varscan2
- OSBPL7 | c.1653C>T p.A551= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs781001344, COSV50106664; called by muse, mutect2, varscan2
- PKD1 | c.10317G>T p.R3439= (on ENST00000262304 / NM_001009944.3; = p.R3438= on NM_000296.4) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99239230; called by muse, mutect2
- SALL4 | c.1131G>A p.A377= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as rs1000652774, COSV53849907; called by muse, mutect2, varscan2
- SLC27A1 | c.855C>T p.L285= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV53095259; called by muse, mutect2, varscan2
- TYK2 | c.1278G>T p.L426= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV53384849; called by muse, mutect2, varscan2
- UPB1 | c.810C>T p.I270= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as rs201827037, COSV58112095; called by muse, mutect2
